Surgical pathology report (de-identified scan), TCGA case TCGA-3H-AB3L, project TCGA-MESO (Mesothelioma), tissue source site MD Anderson Cancer Center, specimen TCGA-3H-AB3L-01A (Primary Tumor).

M

Accession: [REDACTED]
Specimen Date/Time:

ICD O3
Mesothelioma, epithelioid
malignant 905213
Site: Pleura NOS C384
JW 6/13/14

DIAGNOSIS

- (A) PLEURAL TISSUE, BIOPSY:
EPITHELIOID MALIGNANT MESOTHELIOMA (SEE COMMENT)

COMMENT:

Immunohistochemical studies done on tumor sections show positive staining for keratin 5/6, WT1 and calretinin, and negative staining for MOC-31 in the neoplastic cells. The immunohistochemical pattern supports the above diagnosis.

GROSS DESCRIPTION

- (A) PLEURAL TISSUE, RULE OUT TUMOR – Received is a fragment of dark-red soft tissue (1.8 x 0.3 cm). It is submitted entirely for frozen section diagnosis.

*FS/DX: TUMOR PRESENT.

CLINICAL HISTORY

Mesothelioma.

SNOMED CODES

T-29000, M-90503

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 44c3647a-216f-4983-91f7-6ff2bbfc1527 (TCGA-3H-AB3L.162C8370-35C9-4B65-A9F2-6133E343390A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).